Somatic mutation profile of tumor specimen TCGA-P5-A5F4-01A (aliquot TCGA-P5-A5F4-01A-11D-A289-08) from TCGA case TCGA-P5-A5F4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.2 years (12,851 days).
Specimen TCGA-P5-A5F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0a3ec6a-4fb4-463d-9d9c-16a0f9d25846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5F4-10A (Blood Derived Normal), aliquot TCGA-P5-A5F4-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22b74c72-21d6-4d7f-b754-4de3c1fef30c

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 27/30 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO2 | c.2168C>T p.P723L (on ENST00000356134 / NM_001278597.3; = p.P727L on NM_001278596.3) | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV59030713; called by muse, mutect2, varscan2
- ARID4A | c.3176G>C p.S1059T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs763145912, COSV62164864, COSV99049434; called by muse, mutect2, varscan2
- DHRSX | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58135577; called by muse, mutect2, varscan2
- DQX1 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1326837512, COSV66353359; called by muse, mutect2, varscan2
- ERICH5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575526227, COSV59315550; called by muse, mutect2, varscan2
- GATA2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV62005285, COSV62007659; called by muse, mutect2
- GATA4 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1431297203, COSV58734403; called by muse, mutect2, varscan2
- IFT52 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs773600156, COSV65975427; called by muse, mutect2, varscan2
- ITGA5 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53219022; called by muse, mutect2, varscan2
- KLHL7 | c.1727C>G p.T576S (on ENST00000339077 / NM_001031710.3; = p.T528S on NM_018846.5) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.743); catalogued as COSV100178383, COSV59162436; called by muse, mutect2, varscan2
- KRT73 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.074); catalogued as COSV59840100; called by muse, mutect2, varscan2
- KRTAP10-7 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59111297; called by muse, mutect2, varscan2
- OR11H12 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs1410400258, COSV73543698; called by muse, mutect2
- OR5D18 | c.347T>G p.L116* | Nonsense Mutation (SNP) | VAF 73/191 reads (38%) | catalogued as COSV61737743; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2435A>G p.Y812C (on ENST00000259318 / NM_001136562.3; = p.Y1043C on NM_007203.5) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1456140261, COSV52178417; called by muse, mutect2, varscan2
- PDE2A | c.1907G>T p.C636F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.035); catalogued as COSV57809550; called by muse, mutect2, varscan2
- PKP3 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148819261; called by muse, mutect2, varscan2
- PLCB4 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53807085; called by muse, mutect2, varscan2
- PRDM11 | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1187515906, COSV55441407; called by muse, mutect2, varscan2
- PRR5 | c.770C>T p.T257M (on ENST00000336985 / NM_181333.4; = p.T248M on NM_015366.4) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs764906131, COSV99134025; called by muse, mutect2, varscan2
- PWWP3B | c.556T>C p.S186P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1404375880, COSV61800479; called by muse, mutect2, varscan2
- RNF126 | c.346C>G p.H116D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV52778684; called by muse, mutect2, varscan2
- SMC4 | c.521A>C p.D174A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV58449304; called by muse, mutect2, varscan2
- STT3B | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV55504047; called by muse, mutect2
- TMC8 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs149327841, COSV59210391; called by muse, mutect2, varscan2
- ZNF117 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV51428472; called by muse, mutect2, varscan2
- AP2A2 | c.1122C>T p.N374= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs376964234; called by muse, mutect2
- BTK | c.654G>A p.K218= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as CX012301, COSV58117341, COSV58121390; called by muse, mutect2, varscan2
- CYLC1 | c.6T>C p.S2= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100254215, COSV61413488; called by muse, mutect2, varscan2
- FLYWCH1 | c.939G>A p.R313= (on ENST00000253928 / NM_001308068.2; = p.R312= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV54147633; called by muse, mutect2, varscan2
- KRT15 | c.612C>T p.G204= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as rs577866815, COSV54180244; called by muse, mutect2, varscan2
- LARGE1 | c.2226C>T p.Y742= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs777773303, COSV61665152; called by muse, mutect2, varscan2
- PTPRB | c.4089C>T p.C1363= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54245494; called by muse, mutect2, varscan2
- SLCO1B3 | c.828T>C p.F276= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV53940735; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1383T>C p.Y461= | Silent (SNP) | VAF 110/271 reads (41%) | catalogued as rs200041966, COSV60874573; called by muse, mutect2, varscan2
- ZNF430 | c.135T>C p.S45= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV55110925; called by muse, mutect2, varscan2
- HUWE1 | c.1490-744T>C | Intron (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
